Gene-level copy-number profile of tumor specimen TCGA-29-A5NZ-01A from TCGA case TCGA-29-A5NZ, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Specified parts of peritoneum; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.1 years (24,161 days).
Specimen TCGA-29-A5NZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e93181c8-807e-41c7-99a1-93c3eead37f7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-A5NZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 834 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c9c0980-657e-4798-8199-4f51bb3e69ac

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,156; copy number 2: 6,793; copy number 3: 25,047; copy number 4: 16,187; copy number 5: 5,315; copy number 6: 4,047; copy number 7: 406; copy number 8: 91; copy number 9: 8; copy number 10: 27; copy number 11: 14; copy number 12: 90; copy number 15: 160; copy number 18: 1; copy number 19: 58; copy number 22: 27; copy number 27: 150; copy number 29: 68; copy number 32: 34; copy number 33: 110.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-A5NZ-01A-11D-A402-01): tumor purity 0.86, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,244 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,782,671–152,676,574, 160 genes, copy number 15 (broad region; genes not listed).
- chr1:164,343,005–164,357,364, 3 genes, copy number 7: NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr1:194,785,517–194,931,310, 1 gene, copy number 19 (within-gene range 9–19): AL353072.2.
- chr1:196,044,883–196,065,235, 1 gene, copy number 18: LINC01724.
- chr4:60,750,575–62,490,218, 16 genes, copy number 7: LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1.
- chr4:68,784,618–72,808,192, 87 genes, copy number 7 (broad region; genes not listed).
- chr6:167,607–4,703,779, 106 genes, copy number 7 (broad region; genes not listed).
- chr6:4,714,098–4,724,885, 1 gene, copy number 7: AL356747.1.
- chr6:39,792,298–42,217,861, 70 genes, copy number 22–29 (broad region; genes not listed).
- chr6:53,616,471–53,924,125, 4 genes, copy number 8 (within-gene range 6–8): LINC01564, KLHL31, AL590652.1, LRRC1.
- chr11:44,694,863–46,846,308, 59 genes, copy number 22–32 (within-gene range 3–32): LINC02704, TSPAN18-AS1, TSPAN18, TP53I11, LINC02685, AC068858.1, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67.
- chr12:43,835,967–47,943,048, 73 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr12:50,504,985–51,028,566, 17 genes, copy number 12 (within-gene range 4–12): DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2.
- chr12:62,234,390–69,823,204, 181 genes, copy number 11–33 (broad region; genes not listed).
- chr18:36,777,647–39,800,322, 24 genes, copy number 7–9: TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P.
- chr19:11,559,374–16,134,234, 269 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr19:23,525,631–24,163,425, 22 genes, copy number 8 (within-gene range 3–8): ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr22:22,785,643–25,437,823, 150 genes, copy number 27 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 266. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
